Surgical pathology report (de-identified scan), TCGA case TCGA-ZJ-A8QQ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site NCI HRE Branch, specimen TCGA-ZJ-A8QQ-01A (Primary Tumor).

ACCT#: [REDACTED] DOB: [REDACTED]

Specimen #:

Date Obtained:

Date Received:

Dr:

Date Printed:

CLINICAL HISTORY:

RESULTS NEEDED BY

ICD-9: 795.04

ICD-O-3
Carcinoma, large cell, non-keratinizing NOS
Site: Cervix NOS
807293
C53.9
9/26/14

SPECIMEN/PROCEDURE:

1. CERVIX - BX
2. CERVIX - BX

IMPRESSION:

- 1) CERVIX, 6 O'CLOCK, BIOPSY:
- Invasive squamous cell carcinoma, large cell nonkeratinizing type, poorly differentiated.
- 2) CERVIX, 8 O'CLOCK, BIOPSY:
- Invasive squamous cell carcinoma, large cell nonkeratinizing type, poorly differentiated.

Dictated by:

Entered:

COMMENT:

Case reviewed at

Entered:

GROSS DESCRIPTION:

- 1) Received labeled with the patient's name and "cervical biopsy at 6:00", is a pink to pale tan tissue fragment with apparent mucoid material. The specimen is entirely submitted in one cassette.
- 2) Received labeled with the patient's name and "cervical biopsy at 8:00", is a pink to pale tan irregular tissue fragment that is 1.5 x 0.7 x 0.3 cm. The specimen is trisected and entirely submitted in cassette #2.

Dictated by:

Entered:

Patient: [REDACTED] Age/Sex: F Acct# [REDACTED]

Criteria	lw 11/20/13	Yes	No

Source: NCI Genomic Data Commons file ea738850-52ae-42cc-ac84-9be618b487e3 (TCGA-ZJ-A8QQ.C27506F6-D35D-4A7A-8BDA-AC3F72432DAF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).